Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACRT, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACRT-TTP1-A (Primary Tumor).

Sent Material:

- a) Carinal lymph nodes
- b) Medium lobar bronchus lymph node
- c) Right lung
- d) Gland anterior mediastinum

TSS verified lower lobe, (R)

UUID: C54206AA-52A5-42B4-A909-CASE660DF630
CDDP-YP-ACRT-01-PR

**Diagnosis:**

- a) Two lymph nodes free of metastases
- b) One lymph node free of metastases
- c) **Macroscopic report:** sample of pulmonary lobectomy of cm 15x11x3 with pleural retraction area and underlying a grayish malignancy of cm 3x2x2.5
Microscopic report: Adenocarcinoma, moderately differentiated (G2) with wide residual elements of non mucinous bronchiolo alveolar carcinoma. Per TSS, % histologies UNKNOWN. (R)
Bronchial margin pleura and one lobar hilar lymph node free of neoplasia.
Coexist foci of pneumonia in organization and respiratory bronchiolitis due to smoke
- d) Two lymph nodes free of metastases

ICD-0-3

adenocarcinoma, NOS 8140/3

Site (R) lung, lower lobe C34.3

ICD-10

C34.31

12/16/16

Source: NCI Genomic Data Commons file ad473f70-d689-40c2-b120-e05f6529332c (CDDP-ACRT-TTP1.C54206AA-52A5-42B4-A909-CA5E660DF630.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).